Somatic mutation profile of tumor specimen TCGA-D1-A0ZS-01A (aliquot TCGA-D1-A0ZS-01A-11D-A122-09) from TCGA case TCGA-D1-A0ZS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 54.3 years (19,821 days).
Specimen TCGA-D1-A0ZS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 993f5d4a-9f1d-4010-a1ac-a12f47fbeaf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A0ZS-10A (Blood Derived Normal), aliquot TCGA-D1-A0ZS-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8af0fbcd-588c-423c-b495-26d20e1d127c

The open-access MAF lists 493 somatic variants for this specimen: 387 protein-altering or splice-affecting, 93 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 249, Silent 93, Frame Shift Del 80, Frame Shift Ins 28, Nonsense Mutation 17, Intron 9, In Frame Del 6, Splice Site 4, 3'UTR 2, Splice Region 2, RNA 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 25/94 reads (27%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- CUL4B | c.923dup p.L308Ffs*5 | Frame Shift Ins (INS) | VAF 98/260 reads (38%) | catalogued as rs1556216330; ClinVar: pathogenic; called by mutect2, varscan2
- HSD3B2 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs80358221, CM950656, CM993171; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.848del p.G283Afs*23 (on ENST00000642864 / NM_001111125.3; = p.G78Afs*23 on NM_015075.2) | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs782660318, COSV64726734; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 125/380 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 18/64 reads (28%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1370_1381del p.Q457_S460del (on ENST00000521381 / NM_181523.3; = p.Q187_S190del on NM_181504.4) | In Frame Del (DEL) | VAF 63/211 reads (30%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PIK3R1 | c.1746-2A>G p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 196/563 reads (35%) | hotspot (GDC flag); catalogued as COSV57125460, COSV57131831, COSV57142185; called by muse, mutect2, varscan2
- PTEN | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 217/314 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782603, CM109590, CM110122, CM132268, COSV100910106, COSV64289126, COSV64290825; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.1203G>T p.Q401H | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV65907431; called by muse, mutect2, varscan2
- ABCB6 | c.2466G>A p.W822* | Nonsense Mutation (SNP) | VAF 92/211 reads (44%) | catalogued as COSV54697267; called by muse, mutect2, varscan2
- ABCB7 | c.1574A>G p.Q525R (on ENST00000373394 / NM_001271696.3; = p.Q526R on NM_004299.6) | Missense Mutation (SNP) | VAF 139/376 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV53720999; called by muse, mutect2, varscan2
- ABCC4 | c.3392T>C p.M1131T | Missense Mutation (SNP) | VAF 135/383 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1235326392, COSV65314405; called by muse, mutect2, varscan2
- ABHD4 | c.683A>G p.K228R | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.576); catalogued as COSV53529982; called by muse, mutect2, varscan2
- ADAMTS1 | c.2726G>A p.C909Y | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53171332; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2693C>A p.P898H | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV55001907; called by muse, mutect2
- ADARB2 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.419); catalogued as rs373439178, COSV67239937; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 46/118 reads (39%) | catalogued as rs760140619; called by mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 44/163 reads (27%) | catalogued as rs761350619; called by mutect2, varscan2
- AGRN | c.2545T>G p.C849G | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65070463; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 62/203 reads (31%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- ANK1 | c.1603-2A>G p.X535_splice | Splice Site (SNP) | VAF 13/39 reads (33%) | catalogued as COSV55885482; called by muse, mutect2, varscan2
- ANKRD49 | c.208del p.M70Wfs*32 | Frame Shift Del (DEL) | VAF 48/140 reads (34%) | catalogued as rs753570186; called by mutect2, varscan2
- AP2A2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.093); catalogued as COSV59961632; called by muse, mutect2, varscan2
- APOA4 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs757539189, COSV63360643; called by muse, mutect2, varscan2
- ARFGEF2 | c.634A>C p.I212L | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV64213231; called by muse, mutect2, varscan2
- ARHGAP33 | c.1729G>T p.G577W | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.494); catalogued as COSV50128934; called by muse, mutect2
- ARHGEF15 | c.2205G>A p.W735* | Nonsense Mutation (SNP) | VAF 35/97 reads (36%) | catalogued as COSV62725635; called by muse, mutect2, varscan2
- ARID1B | c.3482del p.K1161Sfs*37 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as COSV51655751; called by mutect2, pindel, varscan2
- ARID1B | c.4036G>T p.G1346* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs1554235016, COSV51667900; called by muse, mutect2, varscan2
- ARV1 | c.705_707del p.F235del | In Frame Del (DEL) | VAF 120/386 reads (31%) | catalogued as rs1290170509; called by pindel, varscan2
- ATAD3A | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs548644017, COSV59234242; called by muse, mutect2
- ATAD5 | c.1139T>C p.L380S | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58976002; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs768611141; called by mutect2, varscan2
- ATF7IP | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 50/148 reads (34%) | catalogued as COSV53768016; called by muse, mutect2, varscan2
- ATP13A5 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.247); catalogued as COSV60871183; called by muse, mutect2, varscan2
- ATP9A | c.1388T>C p.I463T | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV58768322; called by muse, mutect2, varscan2
- AVL9 | c.1774dup p.I592Nfs*9 | Frame Shift Ins (INS) | VAF 148/394 reads (38%) | catalogued as rs1431700908; called by mutect2, varscan2
- B3GNT2 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.05); catalogued as rs749110175, COSV57345097; called by muse, mutect2, varscan2
- BAG6 | c.2027C>T p.A676V (on ENST00000676571; = p.A629V on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1290462845, COSV52990296; called by muse, mutect2, varscan2
- BEGAIN | c.947G>A p.S316N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1235095864, COSV62069242; called by muse, mutect2, varscan2
- BIRC6 | c.4163T>G p.I1388S | Missense Mutation (SNP) | VAF 149/457 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV70201753; called by muse, mutect2, varscan2
- BPHL | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs533848752, COSV66743922; called by muse, mutect2, varscan2
- BRWD3 | c.5037G>A p.W1679* | Nonsense Mutation (SNP) | VAF 233/669 reads (35%) | catalogued as COSV64750038; called by muse, mutect2, varscan2
- BSG | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs747487226, COSV61076446; called by muse, mutect2, varscan2
- BTBD11 | c.1928C>T p.S643F (on ENST00000280758 / NM_001018072.2; = p.S180F on NM_001017523.2) | Missense Mutation (SNP) | VAF 119/340 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55027634; called by muse, mutect2, varscan2
- BTBD2 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754684263, COSV55308867; called by muse, mutect2, varscan2
- BTF3L4 | c.101C>G p.A34G | Missense Mutation (SNP) | VAF 15/310 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV57630250; called by muse, mutect2
- CACNA1F | c.3940C>T p.R1314C | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782530813, COSV59905195; called by muse, mutect2, varscan2
- CALD1 | c.1585del p.Q529Rfs*76 (on ENST00000361675 / NM_033138.4; = p.Q274Rfs*76 on NM_004342.7) | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | catalogued as rs1554474721; called by mutect2, pindel, varscan2
- CALML3 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.891); catalogued as rs777995357, COSV59449282; called by muse, mutect2, varscan2
- CAPN10 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54377395; called by muse, mutect2, varscan2
- CASC3 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs748600426, COSV52868136; called by muse, mutect2, varscan2
- CASK | c.1181C>A p.S394Y | Missense Mutation (SNP) | VAF 211/621 reads (34%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.744); catalogued as COSV59369770; called by muse, mutect2, varscan2
- CBLL2 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV60369355; called by muse, mutect2, varscan2
- CCDC116 | c.1429C>A p.L477M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53041134; called by muse, mutect2
- CCDC170 | c.1519C>A p.L507I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53341378, COSV99498421; called by muse, mutect2, varscan2
- CCDC27 | c.1915dup p.L639Pfs*? | Frame Shift Ins (INS) | VAF 40/94 reads (43%) | catalogued as rs751021664; called by mutect2, varscan2
- CCDC40 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs535461092, COSV53900872; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC91 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 66/213 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.443); catalogued as COSV60344328; called by muse, mutect2, varscan2
- CDK14 | c.1273C>T p.R425W (on ENST00000380050 / NM_001287135.2; = p.R407W on NM_012395.3) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs140184613, COSV56040635; called by muse, varscan2
- CEL | c.467G>A p.R156H (on ENST00000673714; = p.R153H on NM_001807.6) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs765232449, COSV60826127; called by muse, mutect2, varscan2
- CELA1 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145791288, COSV99529931; called by muse, mutect2, varscan2
- CEP72 | c.593T>C p.L198P | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53794072; called by muse, mutect2, varscan2
- CEP85 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | catalogued as rs143678426, COSV53328777; called by muse, mutect2, varscan2
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2, varscan2
- CLCN5 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV56584309; called by muse, mutect2, varscan2
- CLUH | c.1594C>T p.R532W (on ENST00000435359; = p.R570W on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs867623639, COSV70928916; called by muse, mutect2, varscan2
- CNTN1 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61641588, COSV61645745; called by muse, mutect2, varscan2
- CNTROB | c.2650C>T p.R884W | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs145111551; called by muse, mutect2, varscan2
- COL5A3 | c.2584C>A p.P862T | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as rs757671228, COSV53413421; called by muse, varscan2
- COL6A1 | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs375452881; called by muse, mutect2, varscan2
- COL6A6 | c.1769T>C p.V590A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1159023458, COSV62029014; called by muse, mutect2, varscan2
- COQ4 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs527905977, COSV55957411; called by muse, mutect2, varscan2
- CPNE6 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as rs149609708; called by muse, mutect2, varscan2
- CRACD | c.2434G>A p.A812T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.187); catalogued as COSV51724705; called by muse, mutect2
- CRTAC1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.86); catalogued as rs149424033; called by muse, mutect2, varscan2
- CRYBG1 | c.3254C>T p.A1085V | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as COSV64812424; called by muse, mutect2, varscan2
- CTCFL | c.83A>G p.K28R | Missense Mutation (SNP) | VAF 103/288 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV54776031; called by muse, mutect2, varscan2
- CXXC1 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.64); catalogued as rs1199504475, COSV53275279; called by muse, mutect2, varscan2
- CXXC1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs750319054, COSV53275295; called by muse, mutect2, varscan2
- DCAF1 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 93/269 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV60043337, COSV60044330; called by muse, mutect2, varscan2
- DCC | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 98/270 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs548959522, COSV71434145; called by muse, mutect2, varscan2
- DCTD | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs17849458, COSV63866858; called by muse, mutect2
- DCTN1 | c.2029T>C p.C677R | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62620794; called by muse, mutect2, varscan2
- DDX25 | c.1271A>G p.D424G | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV54991232; called by muse, mutect2, varscan2
- DDX27 | c.2077del p.E693Rfs*2 | Frame Shift Del (DEL) | VAF 33/135 reads (24%) | catalogued as COSV65601129; called by mutect2, pindel, varscan2
- DDX42 | c.2486G>T p.S829I | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV63790513, COSV63791113; called by muse, mutect2, varscan2
- DGKD | c.2564del p.G855Vfs*48 (on ENST00000264057 / NM_152879.3; = p.G811Vfs*48 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 58/191 reads (30%) | catalogued as rs35538077; called by mutect2, pindel, varscan2
- DLG2 | c.1407G>T p.S469= | Splice Region (SNP) | VAF 28/202 reads (14%) | catalogued as COSV54658023; called by muse, mutect2, varscan2
- DLGAP5 | c.2173A>G p.S725G | Missense Mutation (SNP) | VAF 108/313 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as COSV55963850; called by muse, mutect2, varscan2
- DNAH7 | c.9998G>A p.R3333Q | Missense Mutation (SNP) | VAF 151/369 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1383340880, COSV56758744; called by muse, mutect2, varscan2
- DOK7 | c.810_811del p.H272Lfs*28 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs778227501, COSV60772735; called by mutect2, varscan2
- DRAXIN | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747561573, COSV53843418; called by muse, mutect2, varscan2
- DSP | c.467T>C p.I156T | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.533); catalogued as COSV65793624; called by muse, mutect2
- DUXA | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 222/628 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs748002224, COSV101617126, COSV73729482; called by muse, mutect2, varscan2
- DYRK1A | c.1282delinsTT p.G428Lfs*21 | Frame Shift Ins (INS) | VAF 53/190 reads (28%) | catalogued as COSV58293138; called by pindel, varscan2*
- ECE1 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51666203; called by muse, mutect2, varscan2
- EN1 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54631805; called by muse, mutect2, varscan2
- EOLA2 | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 101/348 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV62207378; called by muse, mutect2, varscan2
- ETV1 | c.414del p.T139Hfs*116 | Frame Shift Del (DEL) | VAF 85/272 reads (31%) | catalogued as COSV54136078; called by mutect2, pindel, varscan2
- FAM155B | c.554dup p.N185Kfs*36 | Frame Shift Ins (INS) | VAF 14/45 reads (31%) | catalogued as rs749254240; called by mutect2, varscan2
- FAM172A | c.309G>T p.E103D | Missense Mutation (SNP) | VAF 89/453 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV67939167; called by muse, mutect2, varscan2
- FAM83B | c.2897C>T p.A966V | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs140364953; called by muse, mutect2, varscan2
- FANCI | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 129/339 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV55529385; called by muse, mutect2, varscan2
- FASTKD1 | c.2399T>C p.M800T | Missense Mutation (SNP) | VAF 21/445 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs946633269, COSV52930736; called by muse, mutect2
- FBN3 | c.1448C>T p.T483I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs776266463, COSV54464602; called by muse, mutect2, varscan2
- FBXW5 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs368494470; called by muse, mutect2, varscan2
- FCMR | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150550509; called by muse, mutect2, varscan2
- FGD1 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as rs1014075574, COSV64309031; called by muse, mutect2, varscan2
- FGF13 | c.68dup p.G24Wfs*28 | Frame Shift Ins (INS) | VAF 94/329 reads (29%) | catalogued as rs766041577; called by mutect2, varscan2
- FGFR4 | c.1547A>G p.D516G | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52805531; called by muse, mutect2, varscan2
- FKBP9 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 106/288 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs752543408, COSV54232267; called by muse, mutect2, varscan2
- FLNA | c.6140C>A p.A2047D (on ENST00000369850 / NM_001110556.2; = p.A2039D on NM_001456.3) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61046114; called by muse, mutect2, varscan2
- FLNA | c.6139G>T p.A2047S (on ENST00000369850 / NM_001110556.2; = p.A2039S on NM_001456.3) | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as COSV61046128; called by muse, mutect2, varscan2
- FOXP4 | c.1600G>A p.A534T (on ENST00000307972 / NM_001012426.1; = p.A521T on NM_138457.3) | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57221012; called by muse, mutect2, varscan2
- FOXRED2 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771457194, COSV53400571; called by muse, mutect2, varscan2
- FREM2 | c.6470A>G p.Q2157R | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV54842203; called by muse, varscan2
- FTSJ3 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771207063, COSV59562937; called by muse, mutect2, varscan2
- GALNT9 | c.1422T>A p.S474R (on ENST00000328957 / NM_001122636.2; = p.S108R on NM_021808.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.543); catalogued as COSV61100467; called by mutect2, varscan2
- GAMT | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs781370953, COSV52039794; called by muse, mutect2, varscan2
- GBP1 | c.1742C>T p.T581M | Missense Mutation (SNP) | VAF 204/647 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs138810487; called by muse, mutect2, varscan2
- GCC1 | c.2035G>A p.V679I | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV58462960; called by muse, mutect2, varscan2
- GIMAP1 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as rs1381304423, COSV56188765; called by muse, mutect2, varscan2
- GJB3 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs375681439; called by muse, mutect2, varscan2
- GMEB2 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56607858; called by muse, mutect2, varscan2
- GMPS | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 27/205 reads (13%) | catalogued as COSV55810294; called by muse, mutect2, varscan2
- GNL2 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 121/336 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.325); catalogued as rs1334652509, COSV56169248, COSV56171120; called by muse, mutect2, varscan2
- GP1BA | c.679T>C p.C227R | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56699934; called by muse, mutect2, varscan2
- GPR173 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.037); catalogued as rs1427100063, COSV60236715; called by muse, mutect2, varscan2
- GPRIN2 | c.865C>T p.H289Y | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV65401383; called by muse, mutect2, varscan2
- GPT2 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60839226; called by muse, mutect2, varscan2
- GYS2 | c.752G>A p.C251Y | Missense Mutation (SNP) | VAF 94/273 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.889); catalogued as COSV53925001; called by muse, mutect2, varscan2
- H1-6 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as rs1215748558, COSV58090816; called by muse, mutect2, varscan2
- H2BC14 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.048); catalogued as rs1307790405, COSV60798122; called by muse, mutect2, varscan2
- HCFC2 | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 109/322 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57559021; called by muse, mutect2, varscan2
- HIF1A | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 93/271 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs142614329; called by muse, mutect2, varscan2
- HMCES | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV67300599; called by muse, mutect2, varscan2
- HOXC6 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV54537343; called by muse, mutect2, varscan2
- IQCJ | c.424A>G p.I142V | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV67333904; called by muse, mutect2, varscan2
- IQUB | c.981G>C p.K327N | Missense Mutation (SNP) | VAF 163/521 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV61240240; called by muse, mutect2, varscan2
- ITGA7 | c.2327C>T p.A776V (on ENST00000555728; = p.A732V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs368879643, COSV57691178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KBTBD6 | c.1714A>G p.T572A | Missense Mutation (SNP) | VAF 28/434 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV65271531; called by muse, mutect2
- KDM4A | c.955G>A p.V319M | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64960023; called by muse, mutect2, varscan2
- KIAA1109 | c.14800A>G p.R4934G | Missense Mutation (SNP) | VAF 116/329 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52679708; called by muse, mutect2, varscan2
- KIF16B | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 102/267 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs371878938, COSV61708278; called by muse, mutect2, varscan2
- KLHDC10 | c.1208C>A p.P403H | Missense Mutation (SNP) | VAF 85/211 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59052473; called by muse, mutect2, varscan2
- KLHL15 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60140812; called by muse, mutect2
- KMT2B | c.5291A>C p.Y1764S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55863694; called by muse, mutect2, varscan2
- LAMB2 | c.4363C>T p.R1455W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs901971113, COSV59734847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LGALS2 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 69/218 reads (32%) | catalogued as COSV50757050; called by muse, mutect2, varscan2
- LIMS1 | c.32A>G p.E11G | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.158); catalogued as COSV57540904; called by muse, mutect2, varscan2
- LRP6 | c.3550C>T p.R1184* | Nonsense Mutation (SNP) | VAF 162/454 reads (36%) | catalogued as rs889282775, COSV53789678; called by muse, mutect2, varscan2
- LRRC46 | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as rs577637902, COSV51636334; called by muse, mutect2, varscan2
- MACF1 | c.1271A>G p.E424G | Missense Mutation (SNP) | VAF 153/391 reads (39%) | catalogued as COSV58382343; called by muse, mutect2, varscan2
- MAGEB4 | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV66775981; called by muse, mutect2, varscan2
- MAML1 | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs370222740; called by muse, mutect2, varscan2
- MANBA | c.2099C>T p.A700V (on ENST00000642252; = p.A654V on NM_005908.4) | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271461004, COSV56966898; called by muse, mutect2, varscan2
- MAST4 | c.3463A>G p.I1155V (on ENST00000403625 / NM_001164664.2; = p.I966V on NM_015183.3) | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.771); catalogued as COSV55130629; called by muse, mutect2, varscan2
- MBTPS1 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs1234493041, COSV58571420; called by muse, mutect2, varscan2
- MCHR1 | c.728G>A p.S243N | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.921); catalogued as rs1184136456, COSV50761663; called by muse, mutect2, varscan2
- MCTP1 | c.1592_1594del p.G531del | In Frame Del (DEL) | VAF 64/206 reads (31%) | catalogued as rs749032818; called by pindel, varscan2
- METTL4 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.235); catalogued as COSV60603974; called by muse, mutect2, varscan2
- MIDEAS | c.1755G>T p.E585D | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54095891; called by muse, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MITF | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as COSV58881727; called by muse, mutect2, varscan2
- MME | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 67/171 reads (39%) | catalogued as rs150836510; called by muse, mutect2, varscan2
- MMP20 | c.359del p.N120Ifs*3 | Frame Shift Del (DEL) | VAF 72/206 reads (35%) | catalogued as rs759614533, CD134338; called by mutect2, varscan2
- MMP3 | c.190dup p.I64Nfs*33 | Frame Shift Ins (INS) | VAF 40/151 reads (26%) | catalogued as rs782038929; called by mutect2, varscan2
- MRPL18 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774164343, COSV51705745; called by muse, mutect2, varscan2
- MT2A | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as COSV55330065; called by muse, mutect2, varscan2
- MTHFD2L | c.1033del p.I345Sfs*48 (on ENST00000395759 / NM_001144978.2; = p.I287Sfs*48 on NM_001004346.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 73/221 reads (33%) | catalogued as rs761538540; called by mutect2, pindel, varscan2
- MTMR3 | c.1813del p.L605* | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | catalogued as COSV60305229; called by mutect2, pindel, varscan2
- MUC15 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 15/392 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV55556539; called by muse, mutect2
- MUSK | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369558015; called by muse, mutect2, varscan2
- MVD | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs750941569, COSV55367788; called by muse, mutect2
- MXRA5 | c.5992G>A p.V1998M | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV54239995; called by muse, mutect2
- MYCBP2 | c.12437C>T p.A4146V (on ENST00000357337; = p.A4184V on NM_015057.5) | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV62025955; called by muse, mutect2, varscan2
- MYF5 | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs145853686; called by muse, mutect2, varscan2
- MYH14 | c.3412G>A p.A1138T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.609); catalogued as COSV51822511; called by muse, mutect2
- MYH8 | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 191/559 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs138755767, COSV67959249; called by muse, mutect2, varscan2
- N4BP3 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV51063668; called by muse, mutect2, varscan2
- NADSYN1 | c.1672T>C p.F558L | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as COSV59813156; called by muse, mutect2, varscan2
- NAP1L1 | c.470A>G p.K157R | Missense Mutation (SNP) | VAF 188/566 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV53875156; called by mutect2, varscan2
- NCOR2 | c.3904del p.H1302Mfs*12 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as COSV100657106; called by mutect2, pindel, varscan2
- NDUFS1 | c.1134-1G>A p.X378_splice | Splice Site (SNP) | VAF 55/163 reads (34%) | catalogued as COSV51911066; called by muse, mutect2, varscan2
- NEIL3 | c.1732G>A p.V578M | Missense Mutation (SNP) | VAF 101/286 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs868615358, COSV52811539, COSV52811849; called by muse, mutect2, varscan2
- NEMF | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 22/452 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as rs774632556, COSV53592818; called by muse, mutect2
- NEUROG3 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV54342469; called by muse, mutect2, varscan2
- NFATC4 | c.2024G>A p.R675H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1206040088, COSV51596838; called by muse, mutect2, varscan2
- NKTR | c.2045G>T p.S682I | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV51773051; called by muse, mutect2, varscan2
- NOC2L | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs958395128, COSV58988589; called by muse, mutect2, varscan2
- NPHS1 | c.3554del p.P1185Rfs*52 | Frame Shift Del (DEL) | VAF 26/85 reads (31%) | catalogued as COSV100800437, COSV62287222; called by mutect2, pindel, varscan2
- NR1H3 | c.601del p.Q201Kfs*13 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | catalogued as rs779801455; called by mutect2, pindel, varscan2
- NUMA1 | c.2486C>T p.A829V | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61187281; called by muse, mutect2
- NWD1 | c.3815C>T p.T1272M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs758051323, COSV60339292; called by muse, mutect2, varscan2
- OBSCN | c.8867G>A p.R2956Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as rs747623752, COSV52742676; called by muse, mutect2, varscan2
- OR11H12 | c.317del p.N106Tfs*25 | Frame Shift Del (DEL) | VAF 88/286 reads (31%) | catalogued as rs747004702; called by mutect2, varscan2
- OR2M5 | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 256/661 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as rs1454720125, COSV63546549, COSV63546601; called by muse, varscan2
- OR2Y1 | c.829del p.Y277Ifs*3 | Frame Shift Del (DEL) | VAF 54/187 reads (29%) | catalogued as COSV57137289; called by mutect2, pindel, varscan2
- OR2Y1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs776793152, COSV57136597; called by muse, mutect2, varscan2
- OR7G3 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as rs779363807, COSV59640532; called by muse, mutect2, varscan2
- OSBPL8 | c.1535T>C p.V512A | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99674707; called by muse, mutect2
- P3H3 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs1555121483, COSV51834417; called by muse, mutect2, varscan2
- PALB2 | c.2639C>T p.A880V | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV55166669; called by muse, mutect2, varscan2
- PAPOLG | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 109/330 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs770308707, COSV53183735; called by muse, mutect2, varscan2
- PARP9 | c.2315G>T p.C772F | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64451067; called by muse, mutect2, varscan2
- PCDHA11 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.033); catalogued as COSV56489368; called by muse, mutect2, varscan2
- PCDHGA1 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65295131; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 70/205 reads (34%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCNX2 | c.5923G>A p.E1975K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0.169); catalogued as rs373041734; called by muse, mutect2, varscan2
- PCNX2 | c.194G>A p.S65N | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as COSV50818802; called by muse, mutect2
- PDZD9 | c.434A>G p.E145G (on ENST00000424898 / NM_001363519.1; = p.E85G on NM_173806.4) | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV51672758; called by muse, mutect2, varscan2
- PEX11G | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as COSV55537141; called by muse, mutect2, varscan2
- PFKM | c.2314C>T p.R772W | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as rs1286672315, COSV56658538; called by muse, mutect2, varscan2
- PHF13 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.151); catalogued as rs367884176, COSV50011176; called by muse, mutect2, varscan2
- PHF20L1 | c.1238G>A p.R413K | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as COSV55194602; called by muse, mutect2, varscan2
- PHLDA1 | c.799C>G p.P267A | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.12); catalogued as COSV56997646; called by muse, mutect2, varscan2
- PI4K2B | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 119/324 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53511938; called by muse, mutect2, varscan2
- POLG2 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 16/297 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV73347031; called by muse, mutect2
- POLI | c.1211T>C p.V404A | Missense Mutation (SNP) | VAF 91/229 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV54190246; called by muse, mutect2, varscan2
- PON3 | c.944G>T p.R315M | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV55700087; called by muse, mutect2
- PPHLN1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs377621404; called by muse, mutect2, varscan2
- PPIG | c.1693C>T p.R565* | Nonsense Mutation (SNP) | VAF 46/342 reads (13%) | catalogued as COSV53644026; called by muse, mutect2, varscan2
- PPP2R2D | c.937T>G p.S313A | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV70779151; called by muse, mutect2, varscan2
- PPP2R5D | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55144894; called by muse, mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 30/68 reads (44%) | catalogued as rs778683789; called by mutect2, varscan2
- PRR14 | c.1354C>A p.P452T | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as rs1428452599, COSV54912474; called by muse, mutect2, varscan2
- PSD3 | c.3082C>T p.R1028C (on ENST00000440756; = p.R1027C on NM_015310.4) | Missense Mutation (SNP) | VAF 83/248 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs764890711, COSV54074352; called by muse, mutect2, varscan2
- PSMB2 | c.422G>C p.S141T | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV64698906; called by muse, mutect2, varscan2
- PTPN6 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.152); catalogued as rs1272459641, COSV59685036; called by muse, mutect2, varscan2
- PTPRF | c.4244G>A p.R1415H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370637531; called by muse, mutect2, varscan2
- PTPRG | c.3078G>A p.W1026* | Nonsense Mutation (SNP) | VAF 49/172 reads (28%) | catalogued as COSV55647763; called by muse, mutect2, varscan2
- PYHIN1 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 74/232 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs373907087; called by muse, mutect2, varscan2
- PYROXD1 | c.194T>A p.V65D | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53710406; called by muse, mutect2, varscan2
- RAB24 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs200543182, COSV57463580; called by muse, mutect2, varscan2
- RAI1 | c.5518G>A p.G1840R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753204826, COSV55394677; called by muse, mutect2
- RAP2C | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61683441; called by muse, varscan2
- RBBP6 | c.3200C>T p.P1067L | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs1458495210, COSV100154576, COSV60506188; called by muse, mutect2, varscan2
- RBBP6 | c.4423dup p.T1475Nfs*2 | Frame Shift Ins (INS) | VAF 74/235 reads (31%) | catalogued as rs747289496; called by mutect2, varscan2
- RENBP | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV64170135; called by muse, mutect2, varscan2
- RNF43 | c.548A>G p.H183R | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1230901623, COSV68458844; called by muse, mutect2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 72/178 reads (40%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- S1PR3 | c.712T>A p.S238T | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.492); catalogued as COSV63980802; called by muse, mutect2, varscan2
- SAMD1 | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.981); catalogued as COSV54115853; called by muse, mutect2, varscan2
- SAMD9L | c.3206A>G p.K1069R | Missense Mutation (SNP) | VAF 79/230 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV59082766; called by muse, mutect2, varscan2
- SC5D | c.39del p.F13Lfs*23 | Frame Shift Del (DEL) | VAF 129/402 reads (32%) | catalogued as rs1185907700; called by mutect2, pindel, varscan2
- SCN4A | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.143); catalogued as rs781033413, COSV101438714, COSV71127474; called by muse, mutect2, varscan2
- SCPEP1 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 100/293 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs746838158, COSV51854705; called by muse, mutect2, varscan2
- SEMA6A | c.2011T>C p.Y671H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56712423; called by muse, mutect2, varscan2
- SERPINA12 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 91/250 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs780070277, COSV57944498; called by muse, mutect2, varscan2
- SESN3 | c.970G>C p.V324L | Missense Mutation (SNP) | VAF 106/297 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.143); catalogued as COSV53585741; called by muse, mutect2, varscan2
- SH2B1 | c.1534del p.E512Sfs*31 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | catalogued as rs1410542268; called by mutect2, pindel
- SH2D4A | c.1166A>G p.D389G | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV56123267; called by muse, varscan2
- SH3RF3 | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs768730435, COSV58689522; called by muse, mutect2, varscan2
- SHC1 | c.1085G>T p.G362V (on ENST00000368445 / NM_183001.5; = p.G252V on NM_003029.5) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs746647299, COSV63534697; called by mutect2, varscan2
- SHISA2 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 51/119 reads (43%) | catalogued as COSV60111131; called by muse, mutect2, varscan2
- SIL1 | c.1223G>A p.C408Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1205787396, COSV54533357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIX5 | c.2056G>A p.G686R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV52179507; called by muse, mutect2, varscan2
- SKP2 | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV57042922; called by muse, mutect2
- SLC22A13 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746160980, COSV61291439; called by muse, mutect2, varscan2
- SLC27A2 | c.1423A>G p.I475V | Missense Mutation (SNP) | VAF 120/348 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV51060051; called by muse, mutect2, varscan2
- SLC27A4 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as rs779524723, COSV55960509; called by muse, mutect2, varscan2
- SLC2A13 | c.935T>A p.V312E | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV55121124; called by muse, mutect2, varscan2
- SLC44A1 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 95/299 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs748507423, COSV58261848; called by muse, mutect2, varscan2
- SLC44A4 | c.8del p.G3Efs*44 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs760348287; called by mutect2, pindel, varscan2
- SLC8A2 | c.2118G>C p.E706D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52637874; called by muse, mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 152/434 reads (35%) | catalogued as rs760667210; called by mutect2, varscan2
- SNF8 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV51727099; called by muse, mutect2, varscan2
- SNX18 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.086); catalogued as COSV57990260; called by muse, mutect2, varscan2
- SNX9 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 24/532 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427985519, COSV67584877; called by muse, mutect2
- SORBS1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.323); catalogued as rs777183418, COSV53357072; called by muse, mutect2, varscan2
- SPOCK3 | c.1280A>G p.D427G | Missense Mutation (SNP) | VAF 237/687 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.243); catalogued as rs753557766, COSV62717220; called by muse, mutect2, varscan2
- SPTBN4 | c.5044C>T p.R1682C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV58953035; called by mutect2, varscan2
- SRRT | c.2362C>A p.P788T | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53821484; called by muse, mutect2
- STAB2 | c.3857C>A p.T1286K | Missense Mutation (SNP) | VAF 146/416 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66341496; called by muse, mutect2, varscan2
- STRA8 | c.493G>T p.G165W (on ENST00000275764; = p.G143W on NM_182489.2) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51962033; called by muse, mutect2, varscan2
- STRIP1 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs762270029, COSV63930752; called by muse, mutect2, varscan2
- STX5 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs542193132, COSV53678619; called by muse, mutect2, varscan2
- SZT2 | c.5012dup p.E1672Rfs*20 (on ENST00000634258 / NM_001365999.1; = p.E1615Rfs*20 on NM_015284.4) | Frame Shift Ins (INS) | VAF 62/174 reads (36%) | catalogued as rs1346209980; called by mutect2, pindel, varscan2
- TBX5 | c.1208G>A p.S403N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as rs773568096, COSV59862510, COSV59866492; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCHP | c.522del p.K174Nfs*26 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs763438715; called by mutect2, varscan2
- TECPR1 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767172301, COSV65784058; called by muse, mutect2, varscan2
- TGM5 | c.1108G>A p.V370I (on ENST00000220420 / NM_201631.4; = p.V288I on NM_004245.4) | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs200175407, COSV55010657; called by muse, mutect2, varscan2
- TLL2 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV63573453; called by muse, mutect2, varscan2
- TM9SF3 | c.214dup p.S72Kfs*7 | Frame Shift Ins (INS) | VAF 119/384 reads (31%) | catalogued as rs760930120; called by mutect2, varscan2
- TMTC1 | c.2310A>G p.A770= (on ENST00000539277 / NM_001193451.2; = p.A662= on NM_175861.3) | Splice Region (SNP) | VAF 114/345 reads (33%) | catalogued as COSV55485378; called by muse, mutect2, varscan2
- TRHR | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 104/315 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251521354, COSV100304588, COSV61235018; called by muse, mutect2, varscan2
- TRIB3 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs142361535; called by muse, mutect2, varscan2
- TRIM52 | c.198G>T p.E66D | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV59844328; called by muse, mutect2, varscan2
- TRIM69 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as COSV100274192; called by muse, mutect2
- TTC13 | c.659A>C p.E220A | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV64168948; called by muse, mutect2, varscan2
- TUB | c.1060T>G p.S354A (on ENST00000299506 / NM_177972.3; = p.S409A on NM_003320.4) | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as COSV55108685; called by muse, mutect2, varscan2
- UNC13B | c.3567G>T p.E1189D | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV65935862; called by muse, mutect2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 84/262 reads (32%) | catalogued as rs767420916; called by mutect2, varscan2
- VSX1 | c.822del p.K274Nfs*5 | Frame Shift Del (DEL) | VAF 43/129 reads (33%) | catalogued as rs780576849; called by mutect2, pindel, varscan2
- WDHD1 | c.2869_2870del p.K957Vfs*14 | Frame Shift Del (DEL) | VAF 136/411 reads (33%) | catalogued as rs1355430116; called by mutect2, pindel, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 34/93 reads (37%) | catalogued as rs746919573; called by mutect2, varscan2
- XRCC6 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 104/249 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as rs1346522683, COSV63753148; called by muse, mutect2, varscan2
- YIF1A | c.641+1G>A p.X214_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as rs777794755, COSV61012660; called by muse, mutect2, varscan2
- YKT6 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 94/231 reads (41%) | catalogued as COSV56272286; called by muse, mutect2, varscan2
- ZBTB24 | c.1909G>A p.V637M | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs750596422, COSV57782498; called by muse, mutect2, varscan2
- ZCCHC4 | c.228dup p.Q77Sfs*5 | Frame Shift Ins (INS) | VAF 98/330 reads (30%) | catalogued as rs766359165; called by mutect2, varscan2
- ZEB1 | c.310G>T p.G104* | Nonsense Mutation (SNP) | VAF 95/274 reads (35%) | catalogued as COSV100313465, COSV58047876; called by muse, mutect2, varscan2
- ZFHX3 | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 44/102 reads (43%) | catalogued as COSV51711886, COSV51742992; called by muse, mutect2, varscan2
- ZFHX4 | c.4175G>A p.R1392H | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs955316426, COSV51452815; called by muse, mutect2, varscan2
- ZFP37 | c.482dup p.N161Kfs*2 | Frame Shift Ins (INS) | VAF 40/142 reads (28%) | catalogued as rs563751025; called by mutect2, varscan2
- ZNF280D | c.2223del p.E742Kfs*62 | Frame Shift Del (DEL) | VAF 63/178 reads (35%) | catalogued as rs1158517703; called by mutect2, pindel, varscan2
- ZNF367 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 94/242 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as rs930166194, COSV64547075; called by muse, mutect2, varscan2
- ZNF480 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.485); catalogued as rs746046422, COSV57996869; called by muse, mutect2, varscan2
- ZNF569 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV57596620; called by muse, mutect2, varscan2
- ZNF626 | c.345del p.G116Dfs*3 | Frame Shift Del (DEL) | VAF 156/539 reads (29%) | catalogued as rs782441698; called by pindel, varscan2
- ZNF781 | c.412T>A p.F138I | Missense Mutation (SNP) | VAF 12/408 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV100669160; called by muse, mutect2
- ZNF862 | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV56224561; called by muse, varscan2
- ZP1 | c.332A>G p.H111R | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.272); catalogued as COSV53925171; called by muse, mutect2, varscan2
- ZSWIM8 | c.2510C>T p.A837V | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs778703928, COSV67133227; called by muse, mutect2, varscan2
- ZZEF1 | c.7228C>A p.L2410M | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67558477; called by muse, mutect2, varscan2
- ADAL | c.651del p.E218Kfs*33 | Frame Shift Del (DEL) | VAF 65/173 reads (38%) | called by mutect2, varscan2
- ADAM18 | c.1229del p.N410Mfs*16 | Frame Shift Del (DEL) | VAF 104/301 reads (35%) | called by mutect2, pindel, varscan2
- AFDN | c.2970_2972del p.L991del | In Frame Del (DEL) | VAF 107/304 reads (35%) | called by mutect2, pindel, varscan2
- ALB | c.1438del p.V480Sfs*2 | Frame Shift Del (DEL) | VAF 33/90 reads (37%) | called by mutect2, pindel, varscan2
- ARFIP1 | c.687_688del p.E229Dfs*7 (on ENST00000353617 / NM_001287432.1; = p.E197Dfs*7 on NM_014447.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 197/604 reads (33%) | called by pindel, varscan2
- ARID1A | c.1650del p.Y551Tfs*68 | Frame Shift Del (DEL) | VAF 56/172 reads (33%) | called by mutect2, pindel, varscan2
- ARID1A | c.6625del p.Q2209Sfs*22 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- ATR | c.809del p.F270Sfs*8 | Frame Shift Del (DEL) | VAF 75/243 reads (31%) | called by mutect2, pindel, varscan2
- BCAR1 | c.1244del p.P415Qfs*56 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- BST1 | c.618del p.F206Lfs*38 | Frame Shift Del (DEL) | VAF 80/301 reads (27%) | called by mutect2, pindel, varscan2
- BZW1 | c.854del p.N285Tfs*11 | Frame Shift Del (DEL) | VAF 122/314 reads (39%) | called by mutect2, varscan2
- CAMSAP2 | c.4449dup p.L1484Tfs*5 (on ENST00000236925 / NM_001297707.2; = p.L1473Tfs*5 on NM_203459.3) | Frame Shift Ins (INS) | VAF 32/99 reads (32%) | called by mutect2, pindel, varscan2
- CASP8AP2 | c.4000del p.S1334Vfs*5 | Frame Shift Del (DEL) | VAF 40/148 reads (27%) | called by mutect2, pindel, varscan2
- CCDC171 | c.631_633del p.E211del | In Frame Del (DEL) | VAF 84/272 reads (31%) | called by pindel, varscan2
- CCDC47 | c.1312del p.R438Efs*8 | Frame Shift Del (DEL) | VAF 111/321 reads (35%) | called by mutect2, pindel, varscan2
- CCT6A | c.748dup p.Y250Lfs*14 | Frame Shift Ins (INS) | VAF 39/121 reads (32%) | called by mutect2, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | called by mutect2, pindel, varscan2
- CHSY1 | c.1715dup p.N573Qfs*3 | Frame Shift Ins (INS) | VAF 68/170 reads (40%) | called by mutect2, pindel, varscan2
- CILP2 | c.1655dup p.A553Gfs*26 | Frame Shift Ins (INS) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- CRTC2 | c.1276del p.H426Tfs*10 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- DRAP1 | c.518del p.P173Rfs*45 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | called by mutect2, pindel, varscan2
- FLNC | c.1867del p.D623Mfs*48 | Frame Shift Del (DEL) | VAF 30/83 reads (36%) | called by mutect2, pindel, varscan2
- FRG2 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- GABRB3 | c.383dup p.S129Vfs*18 | Frame Shift Ins (INS) | VAF 62/181 reads (34%) | called by mutect2, pindel, varscan2
- GCC2 | c.2106del p.K702Nfs*3 | Frame Shift Del (DEL) | VAF 76/186 reads (41%) | called by mutect2, varscan2
- GOLGA8A | c.278A>G p.H93R (on ENST00000432566; = p.H65R on NM_181077.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.316); called by mutect2, varscan2
- GOLM1 | c.539del p.K180Rfs*6 | Frame Shift Del (DEL) | VAF 171/557 reads (31%) | called by mutect2, pindel, varscan2
- GRM7 | c.1767del p.W590Gfs*3 | Frame Shift Del (DEL) | VAF 38/121 reads (31%) | called by mutect2, pindel, varscan2
- GSE1 | c.335dup p.G113Wfs*27 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- IGHG2 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 114/331 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- IGHG4 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 59/407 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 150/213 reads (70%) | called by mutect2, varscan2
- LGMN | c.636del p.R213Efs*34 | Frame Shift Del (DEL) | VAF 49/150 reads (33%) | called by mutect2, pindel, varscan2
- LRRIQ1 | c.1451del p.N484Mfs*4 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- MACF1 | c.13069_13070del p.M4357Efs*3 (on ENST00000372915; = p.M2290Efs*3 on NM_012090.5) | Frame Shift Del (DEL) | VAF 69/241 reads (29%) | called by mutect2, pindel, varscan2
- MLLT6 | c.694A>G p.T232A | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP27 | c.1443del p.A482Hfs*6 | Frame Shift Del (DEL) | VAF 157/555 reads (28%) | called by mutect2, pindel, varscan2
- MMUT | c.1864del p.M622Wfs*26 | Frame Shift Del (DEL) | VAF 90/308 reads (29%) | called by mutect2, pindel, varscan2
- MUC2 | c.3947G>T p.S1316I | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NAP1L1 | c.471del p.D158Mfs*15 | Frame Shift Del (DEL) | VAF 180/619 reads (29%) | called by mutect2, pindel, varscan2
- NRIP1 | c.2788_2789dup p.S930Rfs*8 | Frame Shift Ins (INS) | VAF 39/114 reads (34%) | called by mutect2, varscan2
- NUMA1 | c.25del p.A9Lfs*7 | Frame Shift Del (DEL) | VAF 49/128 reads (38%) | called by mutect2, pindel, varscan2
- OLFML2A | c.1078_1080dup p.A360dup | In Frame Ins (INS) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- OR6Y1 | c.83del p.F28Sfs*15 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- PAX5 | c.852del p.T285Pfs*18 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- PDLIM4 | c.504del p.S169Afs*50 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- PIP4K2B | c.393C>G p.S131R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- PLAGL2 | c.30del p.W11Gfs*15 | Frame Shift Del (DEL) | VAF 29/97 reads (30%) | called by mutect2, pindel, varscan2
- PPFIA3 | c.1685dup p.A563Cfs*17 | Frame Shift Ins (INS) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- RAB4A | c.111dup p.F38Ifs*4 | Frame Shift Ins (INS) | VAF 166/464 reads (36%) | called by mutect2, varscan2
- RALGAPB | c.1573dup p.C525Lfs*2 | Frame Shift Ins (INS) | VAF 135/391 reads (35%) | called by mutect2, pindel, varscan2
- RECQL5 | c.2175del p.S727Pfs*27 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel
- REV3L | c.5974dup p.I1992Nfs*33 | Frame Shift Ins (INS) | VAF 68/217 reads (31%) | called by mutect2, varscan2
- SCLT1 | c.347del p.G116Afs*4 | Frame Shift Del (DEL) | VAF 136/525 reads (26%) | called by pindel, varscan2
- SETD2 | c.7143del p.S2382Lfs*29 | Frame Shift Del (DEL) | VAF 114/340 reads (34%) | called by mutect2, pindel, varscan2
- SIN3A | c.2685del p.F895Lfs*10 | Frame Shift Del (DEL) | VAF 135/384 reads (35%) | called by mutect2, pindel, varscan2
- SLC25A4 | c.888del p.K296Nfs*33 | Frame Shift Del (DEL) | VAF 79/306 reads (26%) | called by mutect2, pindel, varscan2
- SRCAP | c.2510del p.L837Yfs*46 | Frame Shift Del (DEL) | VAF 137/457 reads (30%) | called by mutect2, pindel, varscan2
- STAMBPL1 | c.450dup p.L151Ifs*57 | Frame Shift Ins (INS) | VAF 17/69 reads (25%) | called by mutect2, pindel, varscan2
- STUB1 | c.646del p.S216Lfs*24 | Frame Shift Del (DEL) | VAF 45/141 reads (32%) | called by mutect2, pindel, varscan2
- SZT2 | c.5829del p.P1944Rfs*13 (on ENST00000634258 / NM_001365999.1; = p.P1887Rfs*13 on NM_015284.4) | Frame Shift Del (DEL) | VAF 27/61 reads (44%) | called by mutect2, pindel, varscan2
- TAF1 | c.2436del p.A813Pfs*14 (on ENST00000373790 / NM_138923.4; = p.A834Pfs*14 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 63/200 reads (32%) | called by mutect2, pindel, varscan2
- TIGD6 | c.1199dup p.L401Vfs*14 | Frame Shift Ins (INS) | VAF 54/163 reads (33%) | called by mutect2, pindel, varscan2
- TRPM8 | c.710del p.L237* | Frame Shift Del (DEL) | VAF 46/157 reads (29%) | called by mutect2, pindel, varscan2
- TTPA | c.652dup p.I218Nfs*2 | Frame Shift Ins (INS) | VAF 111/393 reads (28%) | called by mutect2, pindel, varscan2
- UBR4 | c.8406del p.M2803Cfs*16 | Frame Shift Del (DEL) | VAF 26/95 reads (27%) | called by mutect2, pindel, varscan2
- USP40 | c.3199del p.Q1067Rfs*5 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- VCPIP1 | c.2116_2118del p.E706del | In Frame Del (DEL) | VAF 109/386 reads (28%) | called by pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | called by mutect2, pindel, varscan2
- ZNF184 | c.1903dup p.T635Nfs*11 | Frame Shift Ins (INS) | VAF 115/435 reads (26%) | called by mutect2, pindel, varscan2
- AAR2 | c.1140C>T p.G380= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV57924249; called by muse, mutect2, varscan2
- ANKRD35 | c.951G>A p.V317= | Silent (SNP) | VAF 45/137 reads (33%) | catalogued as rs148060696; called by muse, mutect2, varscan2
- ANKRD52 | c.135G>A p.L45= | Silent (SNP) | VAF 74/208 reads (36%) | catalogued as COSV57285347; called by muse, mutect2, varscan2
- ARHGEF5 | c.1179G>A p.A393= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as rs1448646542, COSV50212224; called by mutect2, varscan2
- AZI2 | c.639C>T p.S213= | Silent (SNP) | VAF 198/582 reads (34%) | catalogued as COSV55424400; called by muse, mutect2, varscan2
- B4GALNT2 | c.1401G>A p.V467= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as rs372219129, COSV55926938; called by muse, mutect2, varscan2
- BRINP2 | c.1341T>C p.Y447= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV64178381; called by muse, mutect2, varscan2
- CACNA1I | c.5118G>A p.S1706= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs367902739; called by muse, mutect2, varscan2
- CASZ1 | c.4203G>A p.K1401= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV65458937; called by muse, mutect2, varscan2
- CHPF | c.2208C>T p.C736= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1240932580, COSV60535453; called by muse, mutect2, varscan2
- CSK | c.1338C>T p.H446= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs757869092, COSV54974512; called by muse, mutect2, varscan2
- CYTH1 | c.91C>T p.L31= | Silent (SNP) | VAF 77/217 reads (35%) | catalogued as COSV63121605; called by muse, mutect2, varscan2
- DCDC1 | c.4185C>T p.C1395= (on ENST00000597505 / NM_001367979.1; = p.C502= on NM_020869.3) | Silent (SNP) | VAF 76/217 reads (35%) | catalogued as COSV57997239; called by muse, mutect2, varscan2
- DCHS1 | c.3912C>T p.S1304= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV55038028; called by muse, mutect2, varscan2
- DCLK3 | c.258T>C p.D86= | Silent (SNP) | VAF 56/196 reads (29%) | catalogued as COSV69363732; called by muse, mutect2, varscan2
- DEFB108B | c.87A>G p.E29= | Silent (SNP) | VAF 82/238 reads (34%) | catalogued as COSV60822444; called by muse, mutect2
- DGKI | c.2337C>T p.D779= | Silent (SNP) | VAF 91/266 reads (34%) | catalogued as COSV55957872; called by muse, mutect2, varscan2
- EFCAB6 | c.2013C>T p.D671= | Silent (SNP) | VAF 67/224 reads (30%) | catalogued as rs781536986, COSV53061865; called by muse, mutect2, varscan2
- ELAVL1 | c.726C>T p.S242= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs182490610, COSV60967255; called by muse, mutect2, varscan2
- EMID1 | c.639C>T p.A213= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs760696015, COSV61829894; called by muse, mutect2, varscan2
- F12 | c.99T>G p.A33= | Silent (SNP) | VAF 55/140 reads (39%) | catalogued as COSV53691837; called by muse, mutect2, varscan2
- FAM120A | c.504G>A p.Q168= | Silent (SNP) | VAF 29/284 reads (10%) | catalogued as COSV52906935; called by muse, mutect2, varscan2
- FLNC | c.2890C>T p.L964= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV57958317; called by muse, mutect2, varscan2
- FLNC | c.3456G>A p.V1152= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs1440938123, COSV57958325; called by muse, mutect2, varscan2
- GABRG1 | c.603C>A p.S201= | Silent (SNP) | VAF 68/195 reads (35%) | catalogued as COSV54950739, COSV54956699; called by muse, mutect2, varscan2
- GFRAL | c.483G>A p.P161= | Silent (SNP) | VAF 143/378 reads (38%) | catalogued as rs1453742891, COSV61232353; called by muse, mutect2, varscan2
- GGPS1 | c.525G>A p.P175= | Silent (SNP) | VAF 111/343 reads (32%) | catalogued as rs749914612, COSV51397316; called by muse, mutect2, varscan2
- GJA8 | c.969C>T p.Y323= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs782725212, COSV53788542; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2277C>T p.G759= (on ENST00000265755 / NM_016328.3; = p.G744= on NM_005685.4) | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as COSV56088060; called by muse, mutect2, varscan2
- HYOU1 | c.1854G>A p.E618= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as COSV68216352; called by muse, mutect2
- ITGAX | c.1605G>A p.K535= | Silent (SNP) | VAF 80/189 reads (42%) | catalogued as COSV51647447; called by muse, mutect2, varscan2
- ITGB5 | c.2058C>T p.T686= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs143124119; called by muse, mutect2, varscan2
- ITIH2 | c.2805C>T p.F935= | Silent (SNP) | VAF 60/201 reads (30%) | catalogued as rs1471155220, COSV64433543, COSV64433666; called by muse, mutect2, varscan2
- KAT6B | c.1965C>T p.D655= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs748189151, COSV54749983; called by muse, mutect2
- KCNK9 | c.345G>T p.V115= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV57283931; called by muse, mutect2, varscan2
- KIF4A | c.1104C>T p.A368= | Silent (SNP) | VAF 174/541 reads (32%) | catalogued as COSV65544196; called by muse, mutect2, varscan2
- KLHL32 | c.1239G>A p.L413= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as COSV65112613; called by muse, mutect2, varscan2
- KMT2C | c.13983G>A p.E4661= | Silent (SNP) | VAF 62/154 reads (40%) | catalogued as COSV51456587; called by muse, mutect2, varscan2
- LOXL3 | c.1641G>A p.R547= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV51209234; called by muse, mutect2, varscan2
- LYST | c.4461T>C p.A1487= | Silent (SNP) | VAF 119/345 reads (34%) | catalogued as COSV67708855; called by muse, mutect2, varscan2
- LZTS3 | c.2004T>C p.I668= (on ENST00000329152; = p.I622= on NM_001282533.2) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV53906930; called by muse, mutect2, varscan2
- MAST4 | c.5433C>T p.S1811= (on ENST00000403625 / NM_001164664.2; = p.S1622= on NM_015183.3) | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as rs1303536143, COSV55130643; called by muse, mutect2, varscan2
- MUC5B | c.16251C>T p.P5417= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as rs1012587721, COSV71593482; called by muse, mutect2, varscan2
- MYO1H | c.108C>T p.D36= | Silent (SNP) | VAF 80/193 reads (41%) | catalogued as rs759309359, COSV60444505; called by muse, mutect2, varscan2
- NABP2 | c.402C>A p.S134= | Silent (SNP) | VAF 72/189 reads (38%) | catalogued as COSV57192290; called by muse, mutect2, varscan2
- NEXN | c.1680G>A p.E560= | Silent (SNP) | VAF 58/142 reads (41%) | catalogued as rs1267947085, COSV53933394; called by muse, mutect2, varscan2
- NIPBL | c.7272C>T p.D2424= | Silent (SNP) | VAF 125/324 reads (39%) | catalogued as rs113988530, COSV56956268; called by muse, mutect2, varscan2
- NOC2L | c.1827G>A p.R609= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV58988575; called by muse, mutect2, varscan2
- NOX4 | c.615G>A p.T205= | Silent (SNP) | VAF 101/295 reads (34%) | catalogued as rs777960630, COSV54453134; called by muse, mutect2, varscan2
- NUDT10 | c.87C>T p.R29= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs782132884, COSV62854323; called by muse, mutect2, varscan2
- P3H3 | c.684G>A p.G228= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV51834396; called by muse, mutect2, varscan2
- PCDH17 | c.210C>T p.S70= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV64972201, COSV64973440; called by muse, mutect2, varscan2
- PHTF1 | c.1815A>G p.P605= | Silent (SNP) | VAF 54/187 reads (29%) | catalogued as COSV63367971; called by muse, mutect2, varscan2
- PLCE1 | c.1842G>A p.T614= | Silent (SNP) | VAF 53/176 reads (30%) | catalogued as rs771344723, COSV53340350; called by muse, mutect2, varscan2
- POR | c.1770G>A p.A590= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs1425741371, COSV58694420; called by muse, mutect2, varscan2
- PRPF18 | c.879C>T p.G293= | Silent (SNP) | VAF 96/252 reads (38%) | catalogued as COSV60725633; called by muse, mutect2, varscan2
- RIPK1 | c.1191G>A p.Q397= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV52530222; called by muse, mutect2, varscan2
- RPS21 | c.234C>T p.I78= | Silent (SNP) | VAF 111/298 reads (37%) | catalogued as rs148080704; called by muse, mutect2, varscan2
- SEC16B | c.1284G>A p.T428= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs561650789, COSV100381088, COSV57627305; called by muse, mutect2, varscan2
- SLC25A19 | c.888A>G p.T296= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV55469174; called by muse, mutect2, varscan2
- SLC2A4 | c.510C>T p.G170= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs761318305, COSV50301391; called by muse, mutect2, varscan2
- SLC35D1 | c.813C>T p.Y271= | Silent (SNP) | VAF 99/323 reads (31%) | catalogued as rs372859338; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC4A8 | c.870C>T p.F290= | Silent (SNP) | VAF 73/193 reads (38%) | catalogued as COSV60651319; called by muse, mutect2, varscan2
- SLC4A9 | c.1455C>T p.F485= (on ENST00000507527 / NM_001258428.2; = p.F461= on NM_031467.3) | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV50196444; called by muse, mutect2, varscan2
- SMAD7 | c.813G>A p.T271= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as rs373171169; called by muse, mutect2, varscan2
- SMO | c.1623G>A p.T541= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1356483889, COSV50832248; called by muse, mutect2, varscan2
- SOGA3 | c.1965G>A p.E655= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV64107198; called by muse, mutect2, varscan2
- SORT1 | c.399A>G p.P133= | Silent (SNP) | VAF 144/354 reads (41%) | catalogued as COSV56667519; called by muse, mutect2, varscan2
- SPEN | c.3346C>T p.L1116= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as COSV65363787; called by muse, mutect2, varscan2
- STARD10 | c.807C>A p.A269= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1262798823, COSV58325998; called by muse, mutect2, varscan2
- STK11IP | c.1296G>A p.Q432= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1412119446, COSV55251470; called by muse, mutect2, varscan2
- SUMF1 | c.396T>C p.S132= | Silent (SNP) | VAF 91/243 reads (37%) | catalogued as rs1234380681, COSV55994100; called by muse, mutect2, varscan2
- SYNGAP1 | c.3879C>T p.D1293= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs1340445648, COSV53382871; called by muse, mutect2, varscan2
- TCOF1 | c.699T>A p.S233= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as COSV60350191; called by muse, mutect2, varscan2
- TENM1 | c.3546C>T p.C1182= | Silent (SNP) | VAF 16/314 reads (5%) | catalogued as rs1459197815, COSV64435402; called by muse, mutect2
- THADA | c.4401T>C p.T1467= | Silent (SNP) | VAF 62/366 reads (17%) | catalogued as COSV57686576; called by muse, mutect2, varscan2
- TLL1 | c.66C>T p.Y22= | Silent (SNP) | VAF 95/246 reads (39%) | catalogued as COSV50264329, COSV50296845; called by muse, mutect2, varscan2
- TMEM94 | c.1791C>T p.S597= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as rs142268498; called by muse, mutect2, varscan2
- TOM1L1 | c.936C>T p.A312= | Silent (SNP) | VAF 12/181 reads (7%) | catalogued as COSV61948201; called by muse, mutect2
- TPRG1L | c.699G>A p.A233= | Silent (SNP) | VAF 57/176 reads (32%) | catalogued as rs778402537, COSV54561726; called by muse, mutect2, varscan2
- TRAV13-2 | c.340A>G p.*114= | Silent (SNP) | VAF 51/138 reads (37%) | called by muse, mutect2, varscan2
- TRIM41 | c.513G>A p.L171= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV59320049; called by muse, mutect2, varscan2
- TRPA1 | c.1929G>A p.L643= | Silent (SNP) | VAF 118/306 reads (39%) | catalogued as COSV51565417; called by muse, varscan2
- TRPC4 | c.972A>G p.R324= | Silent (SNP) | VAF 71/213 reads (33%) | catalogued as COSV59005077; called by muse, mutect2, varscan2
- VIPR1 | c.1036C>T p.L346= | Silent (SNP) | VAF 16/286 reads (6%) | catalogued as COSV57297886; called by muse, mutect2
- WEE2 | c.663C>T p.G221= | Silent (SNP) | VAF 141/413 reads (34%) | catalogued as rs774017102, COSV66879401; called by muse, mutect2, varscan2
- ZAN | c.138C>T p.D46= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs374893086; called by muse, mutect2, varscan2
- ZAN | c.6171C>A p.I2057= | Silent (SNP) | VAF 50/154 reads (32%) | catalogued as COSV61810893; called by muse, mutect2, varscan2
- ZBED1 | c.537C>T p.A179= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs370752942, COSV100585630, COSV58133041; called by muse, mutect2, varscan2
- ZNF165 | c.192C>T p.R64= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as rs758024716, COSV66102702; called by muse, mutect2, varscan2
- ZNF324B | c.1263C>T p.G421= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV60742384; called by muse, varscan2
- ZNF358 | c.888C>T p.C296= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV51174105; called by muse, mutect2
- ZNF678 | c.468C>T p.D156= (on ENST00000343776 / NM_001367910.1; = p.D211= on NM_178549.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/127 reads (35%) | catalogued as rs771092722, COSV59382281, COSV59387529; called by muse, mutect2, varscan2
- ANKRD13D | c.*1243G>A | 3'UTR (SNP) | VAF 39/99 reads (39%) | catalogued as COSV57385356; called by muse, mutect2, varscan2
- ATP5MD | c.-9-1824G>A | Intron (SNP) | VAF 66/163 reads (40%) | catalogued as rs767749213, COSV58915317; called by muse, varscan2
- DAPP1 | c.774+484G>A | Intron (SNP) | VAF 100/314 reads (32%) | catalogued as rs774642237, COSV99596697; called by muse, mutect2, varscan2
- MGAM | c.4618+282T>C | Intron (SNP) | VAF 69/203 reads (34%) | catalogued as COSV72074963; called by muse, mutect2, varscan2
- MIR543 | n.30del | RNA (DEL) | VAF 143/449 reads (32%) | called by mutect2, pindel, varscan2
- MSH5 | c.538-26C>A | Intron (SNP) | VAF 64/170 reads (38%) | catalogued as COSV65210233, COSV65210376; called by muse, mutect2, varscan2
- NEK6 | c.-29-8990C>A | Intron (SNP) | VAF 40/116 reads (34%) | catalogued as COSV57218826; called by muse, mutect2, varscan2
- NMB | c.*45C>A | 3'UTR (SNP) | VAF 19/180 reads (11%) | catalogued as COSV64685585; called by muse, mutect2, varscan2
- SERPINA13P | n.848T>C | RNA (SNP) | VAF 26/55 reads (47%) | catalogued as rs535162640; called by muse, mutect2, varscan2
- SLC39A14 | c.457+1582C>T | Intron (SNP) | VAF 59/179 reads (33%) | catalogued as rs765639239, COSV51483837; called by muse, mutect2, varscan2
- TTF2 | c.2977-605G>A | Intron (SNP) | VAF 61/161 reads (38%) | catalogued as rs576504987, COSV65632967; called by muse, mutect2, varscan2
- XKR6 | c.765-110394_765-110392del | Intron (DEL) | VAF 22/97 reads (23%) | called by mutect2, pindel, varscan2
